CPTAC case C3L-07981 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78a977d5-c0e0-4a3d-86b1-573f1542447f

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 68.9 years (25,157 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Residual disease: R1; Days to last known disease status: 1,107 days (3.0 years); Progression or recurrence: no; Days to last follow up: 1,107 days (3.0 years); Tumor focality: Multifocal.
   Pathology details: Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 35 days; Days to treatment end: 77 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 315 days; Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 804 days (2.2 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07981-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -20 days; Initial weight: 305 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07981-24: Section location: Antrum, Pylorus; Percent tumor nuclei: 70; Percent necrosis: 3.
- Sample C3L-07981-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -20 days; Method of sample procurement: Blood Draw.
